Gene-level copy-number profile of tumor specimen TCGA-B6-A0WW-01A from TCGA case TCGA-B6-A0WW, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage X; Age at diagnosis: 58.8 years (21,479 days).
Specimen TCGA-B6-A0WW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.5494421e-ace6-4315-8337-edbd09f2e30e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A0WW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/56342e9f-fc44-4dd1-87ba-69abd9da3eee

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 12,837; copy number 2: 40,557; copy number 3: 2,038; copy number 4: 260; copy number 5: 2,552; copy number 7: 1,336; copy number 8: 65; copy number 9: 20; copy number 10: 53; copy number 11: 29; copy number 12: 4; copy number 17: 40.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B6-A0WW-01A-11D-A107-01): tumor purity 0.73, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:27,414,462–28,679,865, 22 genes: AL049536.1, AL050402.2, AL050402.1, AL133456.1, AL121885.2, AL121885.3, AL121885.1, MN1, PITPNB, TTC28-AS1, AL031591.2, MIR3199-1, MIR3199-2, AL031591.1, TTC28, AL033538.1, AL033538.2, RN7SL757P, SNORD42, Y_RNA, MIR5739, RN7SL162P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,099 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,487,364–248,919,946, 2,348 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:33,473,386–34,346,731, 20 genes, copy number 9 (within-gene range 1–9): TTI2, MAK16, SNORD13, AC091144.1, SNORA70, RPL10P18, RNF122, RN7SL621P, DUSP26, AF279873.3, BUD31P1, RN7SL457P, VENTXP5, AF279873.2, AF279873.1, AF279873.4, AC087855.2, AC090993.1, AC087855.1, RPL10AP3.
- chr8:36,764,445–36,764,551, 1 gene, copy number 8: RNA5SP264.
- chr8:37,326,575–38,382,272, 43 genes, copy number 7 (within-gene range 1–7): AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2.
- chr8:40,298,697–47,738,164, 123 genes, copy number 5–8 (broad region; genes not listed).
- chr8:47,805,079–47,805,179, 1 gene, copy number 5: Y_RNA.
- chr8:50,762,460–53,540,300, 34 genes, copy number 5: CYCSP22, AC087272.1, AC090919.1, AC012413.1, PXDNL, BRIX1P1, BTF3P1, AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3, ST18, AC021915.2, AC021915.1, AC103831.1, RPL34P17, ALKAL1, RB1CC1, AC113139.1, NPBWR1, AC009800.1, AC009646.1, AC009646.2, OPRK1, AC131902.1, AC022034.3, AC131902.2, AC022034.1, AC022034.4, AC022034.2, MAPK6P1.
- chr8:64,331,927–145,066,685, 1,267 genes, copy number 5–7 (broad region; genes not listed).
- chr9:8,858,127–9,442,380, 4 genes, copy number 12: PTPRD-AS1, AL596451.1, RPS26P3, RN7SL5P.
- chr9:34,521,043–35,405,338, 44 genes, copy number 5–11 (within-gene range 2–11): ENHO, AL160270.1, AL160270.2, CNTFR, CNTFR-AS1, RPP25L, DCTN3, ARID3C, SIGMAR1, GALT, AL162231.3, IL11RA, CCL27, AL162231.4, AL162231.1, AL162231.2, CCL19, AL162231.5, CCL21, FAM205A, AL589645.1, FAM205BP, FAM205C, GLULP4, YWHAZP6, PHF24, DNAJB5-DT, DNAJB5, AL355377.1, AL355377.2, SYF2P2, AL355377.3, AL355377.4, AL353795.3, C9orf131, RN7SL338P, VCP, FANCG, PIGO, AL353795.2, STOML2, FAM214B, AL353795.1, UNC13B.
- chr11:66,682,497–71,524,107, 161 genes, copy number 5–17 (within-gene range 1–17) (broad region; genes not listed).
- chr22:19,667,023–20,592,218, 53 genes, copy number 10: AC000067.1, SEPTIN5, AC000093.1, GP1BB, TBX1, GNB1L, AC000089.1, RTL10, TXNRD2, AC000078.1, COMT, MIR4761, ARVCF, TANGO2, MIR185, AC006547.1, AC006547.3, Metazoa_SRP, DGCR8, MIR3618, MIR1306, AC006547.2, TRMT2A, MIR6816, RANBP1, SNORA77B, ZDHHC8, CCDC188, AC007663.2, LINC00896, RTN4R, MIR1286, AC007663.1, DGCR6L, AC007663.4, AC007663.3, FAM230G, AC007731.2, AC007731.5, USP41, ZNF74, RNU6-225P, SCARF2, AC007731.4, KLHL22, AC007731.1, RNY1P9, Y_RNA, RN7SL812P, KRT18P5, MED15, AC007731.3, CCDC74BP1.

Autosomal genes at a single copy (total copy number 1): 12,837. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
